Somatic mutation profile of tumor specimen ALCH-AEOP-TTP1-A (aliquot ALCH-AEOP-TTP1-A-2-0-D-A627-36) from ALCHEMIST case ALCH-AEOP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.8 years (21,836 days).
Specimen ALCH-AEOP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6748c8dc-cb49-4ed1-be9b-2c939df2c19a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOP-NB1-A (Blood Derived Normal), aliquot ALCH-AEOP-NB1-A-1-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4cbaf59-703e-4909-a923-d248318e2f77

The open-access MAF lists 196 somatic variants for this specimen: 143 protein-altering or splice-affecting, 37 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 37, Intron 8, RNA 4, 5'Flank 3, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 30/291 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-2A>T p.X187_splice | Splice Site (SNP) | VAF 44/459 reads (10%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2
- AC100868.1 | c.1534del p.D512Tfs*5 | Frame Shift Del (DEL) | VAF 11/106 reads (10%) | catalogued as COSV51843023; called by mutect2, pindel, varscan2
- ADAD1 | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs750588003; called by muse, mutect2, varscan2
- ANGPT1 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 46/534 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52437082; called by muse, mutect2
- CD109 | c.1586C>A p.A529D | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54654511; called by muse, mutect2
- CDK10 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 57/450 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as rs1438771265; called by muse, mutect2, varscan2
- CREBRF | c.1310A>G p.Y437C | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs574369785; called by muse, mutect2, varscan2
- CYP3A7 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 94/560 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs767750768; called by muse, mutect2, varscan2
- DCLK1 | c.2161G>C p.E721Q (on ENST00000360631 / NM_001330072.2; = p.E414Q on NM_001195416.2) | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.188); catalogued as COSV99708907; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 10/62 reads (16%) | catalogued as rs754135731; called by mutect2, varscan2*
- GGT6 | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs1310834748; called by muse, mutect2, varscan2
- GRM1 | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV51115368; called by muse, mutect2
- H3C8 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59952617; called by muse, mutect2
- IAH1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776782313; called by mutect2, varscan2
- IGHM | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 66/537 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.691); catalogued as rs370839878; called by mutect2, varscan2
- INPP4A | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as rs909251709; called by muse, mutect2
- KLHL1 | c.1415G>T p.G472V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64786968; called by muse, mutect2, varscan2
- KRTAP21-1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.046); catalogued as COSV58646563; called by muse, mutect2, varscan2
- LCE2A | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1474103209; called by muse, mutect2
- LRFN5 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 25/318 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53246439; called by muse, mutect2
- MAP7D3 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100286169; called by muse, mutect2, varscan2
- MICALL2 | c.2585G>T p.R862L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52514062; called by muse, mutect2
- NBEA | c.7865G>A p.R2622Q | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.053); catalogued as COSV100082845; called by muse, mutect2
- NDUFV1 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 58/566 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); catalogued as COSV59596226; called by muse, mutect2
- NXPH2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs762302492, COSV55640204, COSV55644337; called by muse, mutect2, varscan2
- OR8K3 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV57131280; called by muse, mutect2
- P3H2 | c.1229+1G>T p.X410_splice | Splice Site (SNP) | VAF 52/596 reads (9%) | catalogued as rs756359436, COSV100077945; called by muse, mutect2
- PCDH8 | c.2521C>A p.P841T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as rs1293292772; called by muse, mutect2, varscan2
- PCDHB13 | c.2212G>T p.D738Y | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs782117089; called by muse, mutect2
- PIK3CA | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1175225456; called by muse, mutect2
- PLCE1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV53347412, COSV53353511; called by muse, mutect2
- RTN1 | c.1127C>A p.P376Q | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV50733280; called by muse, mutect2, varscan2
- RYR2 | c.8917C>G p.Q2973E | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV100768561; called by muse, mutect2
- SLC24A2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99645982; called by muse, mutect2, varscan2
- SLC2A14 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs1007285618; called by muse, mutect2
- SLCO6A1 | c.2080C>A p.R694S | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs769220825, COSV65806886, COSV65809063; called by muse, mutect2, varscan2
- SLITRK3 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV53854422, COSV99579204; called by muse, mutect2
- SP7 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs998278504; called by muse, mutect2
- STRN3 | c.1630A>G p.N544D (on ENST00000357479 / NM_001083893.2; = p.N460D on NM_014574.4) | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV62579375; called by muse, varscan2
- TAS2R10 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.179); catalogued as rs562189619; called by muse, mutect2
- TBL1XR1 | c.204+1G>T p.X68_splice | Splice Site (SNP) | VAF 72/312 reads (23%) | catalogued as COSV61791041; called by muse, mutect2, varscan2
- TENM2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 44/470 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV72853525; called by muse, mutect2
- TGFBRAP1 | c.648A>G p.I216M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs1374351343; called by muse, mutect2
- TNR | c.270G>T p.E90D | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV54910549; called by muse, mutect2
- TRAM1 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs768926473, COSV99140729; called by muse, mutect2
- WARS1 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59924890; called by muse, mutect2, varscan2
- ZFYVE28 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.015); catalogued as rs141400000; called by muse, mutect2
- ZNF418 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as rs1421820464; called by muse, mutect2
- ZNF682 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.123); catalogued as rs1214499932; called by muse, mutect2, varscan2
- ZNF850 | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 19/228 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs765398286, COSV74024362; called by muse, mutect2
- ABCA13 | c.7931C>G p.S2644C | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ADGRF5 | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by mutect2, varscan2
- AKAP9 | c.11656_11667del p.L3886_S3889del (on ENST00000359028; = p.L3862_S3865del on NM_005751.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 59/430 reads (14%) | called by mutect2, pindel, varscan2
- BCHE | c.22A>T p.I8L | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2
- C10orf120 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 37/249 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- C11orf87 | c.247C>A p.H83N | Missense Mutation (SNP) | VAF 19/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C18orf32 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- C7orf25 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- CACNA2D4 | c.2377T>A p.F793I | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2
- CAMK2B | c.302A>G p.D101G | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); called by muse, mutect2
- CCDC144A | c.4048C>G p.P1350A | Missense Mutation (SNP) | VAF 52/834 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2
- CDHR2 | c.2617T>A p.S873T | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CIP2A | c.2644T>C p.S882P | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COL21A1 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 32/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A1 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- COL6A6 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- CSF2RB | c.1712C>G p.P571R | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2
- CSMD2 | c.2479G>T p.V827F | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CXorf66 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.239); called by muse, mutect2
- DCC | c.2900G>T p.W967L | Missense Mutation (SNP) | VAF 25/506 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DENND5B | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIP2C | c.3776G>T p.R1259L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.239); called by muse, mutect2
- DNMT3B | c.209T>G p.L70W | Missense Mutation (SNP) | VAF 65/318 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- EFCAB13 | c.2275A>C p.N759H | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); called by muse, mutect2
- EVC2 | c.1613A>C p.H538P | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- FRAS1 | c.3427G>T p.V1143L | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2
- GADL1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.632); called by muse, mutect2
- GATA6 | c.1494A>G p.I498M | Missense Mutation (SNP) | VAF 29/445 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- GPKOW | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GPR156 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, varscan2
- HMCN1 | c.8243C>T p.S2748F | Missense Mutation (SNP) | VAF 31/580 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- IGLV3-9 | c.327G>T p.W109C | Missense Mutation (SNP) | VAF 36/328 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by mutect2, varscan2
- IL21R | c.1333C>A p.L445I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KIF4A | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- KRTAP10-4 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 34/390 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LOXHD1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP1LC3B | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.215); called by muse, mutect2
- MATN2 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MCCC2 | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ME2 | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2
- MRGPRD | c.466A>T p.M156L | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- MS4A14 | c.1555G>C p.D519H | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MS4A5 | c.313G>T p.V105L | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MSH4 | c.2288G>A p.R763K | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2
- MTRR | c.191G>A p.C64Y (on ENST00000264668; = p.C37Y on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/836 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MUC12 | c.2227G>C p.G743R (on ENST00000379442; = p.G600R on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/800 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MUC5AC | c.16069T>C p.C5357R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYT1 | c.3050C>T p.S1017F | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH4 | c.4758T>A p.D1586E | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2
- NPL | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 28/290 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2
- NPTX2 | c.828del p.N277Tfs*5 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- NUSAP1 | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR14A2 | c.302T>C p.L101S | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2
- OR4X1 | c.827T>C p.V276A | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- PAK3 | c.846dup p.Y283Ifs*5 (on ENST00000262836 / NM_001324328.2; = p.Y268Ifs*5 on NM_002578.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 29/194 reads (15%) | called by pindel, varscan2
- PCDHB11 | c.320A>T p.Q107L | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- PKHD1L1 | c.509C>A p.T170N | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- PLA2G1B | c.371C>G p.A124G | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PNPLA3 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- PRODH2 | c.1087G>T p.D363Y (on ENST00000301175; = p.D287Y on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- PRPF38B | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRB | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.165); called by muse, mutect2
- RALGAPA2 | c.3657G>C p.Q1219H | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.375); called by muse, mutect2
- RASGRF2 | c.3384G>C p.K1128N | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2
- RETREG1 | c.1265C>T p.T422I (on ENST00000306320 / NM_001034850.2; = p.T281I on NM_019000.4) | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RNF215 | c.362C>A p.A121E | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRP8 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR3 | c.4511C>G p.P1504R | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SGCZ | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC17A8 | c.1070C>A p.A357E | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2
- SLC37A4 | c.133G>T p.D45Y | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- SLC6A5 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- SLC9A3 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SSX5 | c.247G>T p.D83Y (on ENST00000347757 / NM_175723.1; = p.D124Y on NM_021015.4) | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2
- SYT3 | c.1467C>G p.I489M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TBX22 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TNNI3 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 30/656 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- TNNT2 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 20/518 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2
- TRDMT1 | c.29A>G p.Y10C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSEN34 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 14/428 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- TSPAN15 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- USH2A | c.9766C>A p.H3256N | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- USH2A | c.1903A>T p.I635L | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- USP30 | c.88A>G p.K30E | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- VWF | c.5521G>A p.G1841S | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- WDFY3 | c.10050C>G p.N3350K | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- WDFY4 | c.4867G>T p.G1623W | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR7 | c.3876G>C p.Q1292H | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.735); called by muse, mutect2
- ZFHX4 | c.8278G>A p.A2760T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ZNF443 | c.1517G>C p.C506S | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF729 | c.3469G>T p.E1157* | Nonsense Mutation (SNP) | VAF 28/300 reads (9%) | called by muse, mutect2
- ZNF786 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ABCC9 | c.666G>A p.L222= | Silent (SNP) | VAF 29/222 reads (13%) | catalogued as COSV99685436; called by muse, mutect2, varscan2
- ACTC1 | c.216C>A p.P72= | Silent (SNP) | VAF 27/198 reads (14%) | catalogued as rs1346123657; called by muse, mutect2, varscan2
- ADGRA1 | c.1416C>T p.C472= | Silent (SNP) | VAF 18/173 reads (10%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.876G>A p.E292= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs782561617; called by muse, mutect2, varscan2
- CCL23 | c.171C>A p.T57= | Silent (SNP) | VAF 27/176 reads (15%) | called by muse, mutect2, varscan2
- CCNA1 | c.1134A>G p.P378= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as rs1170649401; called by muse, mutect2, varscan2
- CSMD1 | c.4143C>T p.S1381= (on ENST00000520002; = p.S1380= on NM_033225.6) | Silent (SNP) | VAF 18/128 reads (14%) | called by muse, mutect2, varscan2
- DACT2 | c.777G>A p.K259= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- DDHD2 | c.279G>A p.L93= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- DSEL | c.474T>C p.Y158= | Silent (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- FBXW10 | c.2439C>T p.D813= | Silent (SNP) | VAF 62/532 reads (12%) | called by muse, mutect2, varscan2
- GRM1 | c.228C>A p.I76= | Silent (SNP) | VAF 17/313 reads (5%) | catalogued as COSV51114289, COSV51180353; called by muse, mutect2
- HHLA1 | c.1113G>A p.A371= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs1019577195; called by muse, mutect2, varscan2
- HSPG2 | c.321G>A p.E107= | Silent (SNP) | VAF 19/522 reads (4%) | called by muse, mutect2
- HTR5A | c.36C>G p.L12= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- IGKV2D-30 | c.132G>A p.R44= | Silent (SNP) | VAF 14/132 reads (11%) | called by mutect2, varscan2
- ITGB1 | c.1203C>T p.C401= | Silent (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2, varscan2
- KIF13A | c.4122C>G p.T1374= | Silent (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2, varscan2
- LCE1E | c.171G>T p.G57= | Silent (SNP) | VAF 42/394 reads (11%) | catalogued as rs1352879440; called by muse, mutect2, varscan2
- LIG1 | c.1860C>T p.T620= | Silent (SNP) | VAF 51/434 reads (12%) | catalogued as rs757371674; called by muse, mutect2, varscan2
- LRP1B | c.4533A>T p.A1511= | Silent (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- LRRTM1 | c.480G>T p.L160= | Silent (SNP) | VAF 24/264 reads (9%) | called by muse, mutect2
- MAGEA12 | c.555C>A p.S185= | Silent (SNP) | VAF 39/205 reads (19%) | called by muse, mutect2, varscan2
- MARCHF11 | c.474C>A p.R158= | Silent (SNP) | VAF 44/145 reads (30%) | called by muse, mutect2, varscan2
- MTOR | c.4581C>T p.D1527= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- MUC16 | c.11265G>A p.Q3755= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV67501557; called by muse, mutect2, varscan2
- NGFR | c.615G>C p.S205= | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as rs377669981; called by muse, mutect2
- OCSTAMP | c.909G>A p.L303= | Silent (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2, varscan2
- PID1 | c.531C>T p.P177= (on ENST00000354069 / NM_001330156.1; = p.P175= on NM_017933.5) | Silent (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- PNCK | c.552G>A p.L184= (on ENST00000340888 / NM_001366975.1; = p.L267= on NM_001039582.3) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1364062503; called by muse, mutect2, varscan2
- PRPF40A | c.432A>C p.V144= | Silent (SNP) | VAF 17/241 reads (7%) | called by muse, mutect2
- RNF169 | c.1488C>T p.P496= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2, varscan2
- RPUSD3 | c.393C>T p.V131= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- SCNN1B | c.1548C>A p.V516= | Silent (SNP) | VAF 40/386 reads (10%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.630C>T p.L210= | Silent (SNP) | VAF 33/348 reads (9%) | catalogued as rs1285163368; called by muse, mutect2
- TTC3 | c.3429A>T p.R1143= | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- ZNF8 | c.741C>T p.L247= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- AC125421.1 | n.325-195G>T | Intron (SNP) | VAF 36/356 reads (10%) | called by muse, mutect2, varscan2
- AGAP7P | n.1073T>C | RNA (SNP) | VAF 60/676 reads (9%) | called by muse, mutect2
- AGRN | c.5652-32del | Intron (DEL) | VAF 31/267 reads (12%) | called by mutect2, pindel, varscan2
- CCSER1 | c.2095-12084G>A | Intron (SNP) | VAF 28/334 reads (8%) | catalogued as rs73834578; called by muse, mutect2
- FAM230J | n.304A>T | RNA (SNP) | VAF 14/460 reads (3%) | called by muse, mutect2
- FOXP2 | c.*2885G>T | 3'UTR (SNP) | VAF 13/75 reads (17%) | catalogued as rs1291313903; called by muse, mutect2, varscan2
- H3-3B | chr17:75784718 A>G | 5'Flank (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
- IGFN1 | c.1241+2707G>A | Intron (SNP) | VAF 6/98 reads (6%) | catalogued as COSV55184638; called by muse, mutect2
- LHX9 | chr1:197916692 A>G | 5'Flank (SNP) | VAF 36/360 reads (10%) | called by muse, mutect2
- LINC02054 | n.2363C>G | RNA (SNP) | VAF 17/207 reads (8%) | called by muse, mutect2
- METTL6 | c.532-684G>T | Intron (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- PPP1R9A | c.2757+625C>G | Intron (SNP) | VAF 40/250 reads (16%) | catalogued as COSV99198646; called by muse, mutect2, varscan2
- PTGDS | c.551-124G>C | Intron (SNP) | VAF 24/168 reads (14%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3028A>G | RNA (SNP) | VAF 11/95 reads (12%) | catalogued as rs752375163; called by muse, mutect2, varscan2
- SYNE1 | c.310-478G>T | Intron (SNP) | VAF 47/390 reads (12%) | called by muse, varscan2
- THNSL2 | chr2:88171306 G>T | 5'Flank (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
